Gene-level copy-number profile of specimen HCM-CSHL-0582-C18-85M from HCMI case HCM-CSHL-0582-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 56.2 years (20,518 days).
Specimen HCM-CSHL-0582-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1876d1de-20f8-4fa7-9d1a-a2c16508df17.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0582-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/5d7c58df-e66b-4363-b774-78648f25ec20

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,166; copy number 2: 24,624; copy number 3: 20,075; copy number 4: 8,045; copy number 5: 1,520; copy number 6: 993; copy number 7: 929; copy number 8: 560.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,002 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,791,397–12,841,357, 4 genes, copy number 5: PRAMEF1, LINC01784, PRAMEF11, PRAMEF30P.
- chr1:149,048,576–193,254,815, 1,185 genes, copy number 5 (broad region; genes not listed).
- chr1:194,188,967–205,211,702, 216 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:42,890,265–48,214,794, 125 genes, copy number 6–8 (broad region; genes not listed).
- chr6:170,615,515–170,738,536, 5 genes, copy number 5: AL672310.1, OR4F7P, WBP1LP8, AL731661.1, AL731684.1.
- chr7:156,186,122–159,233,377, 48 genes, copy number 5: Y_RNA, AC093813.1, LINC01006, LINC00244, AC005534.1, RNF32, RNF32-AS1, LMBR1, RNU4-31P, AC006357.1, NOM1, MNX1, MNX1-AS2, MNX1-AS1, AC006967.2, AC006967.1, AC006967.3, UBE3C, RPS27AP12, AC004898.1, AC004975.1, AC004975.2, DNAJB6, AC006372.3, AC006372.1, AC006372.2, AC006372.4, PTPRN2, MIR153-2, AC005481.1, AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr12:42,069,935–44,921,848, 41 genes, copy number 5 (within-gene range 4–5): AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, NELL2.
- chr13:18,467,172–114,337,626, 1,330 genes, copy number 6–8 (broad region; genes not listed).
- chr15:88,459,477–89,398,487, 35 genes, copy number 5–7: MRPL46, AC013489.1, MRPS11, AC013489.3, DET1, AC013489.2, LINC01586, MIR1179, MIR7-2, MIR3529, AEN, ISG20, AC103982.1, ACAN, HAPLN3, MFGE8, AC067805.1, KRT18P47, AC107954.1, AC013565.2, AC013565.1, AC013565.3, ABHD2, RNU7-195P, HMGB1P8, AC124068.1, RLBP1, FANCI, POLG, MIR6766, AC124068.2, AC133637.1, AC133637.2, MIR9-3HG, MIR9-3.
- chr15:90,001,324–90,502,239, 29 genes, copy number 5–6: ZNF710, MIR3174, AC087284.1, ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P, GABARAPL3, GABARAPL3, ZNF774, NDUFA3P4, IQGAP1, AC018946.1.
- chr15:92,883,413–93,760,886, 11 genes, copy number 6 (within-gene range 2–6): AC013394.1, CHD2, MIR3175, RGMA, YBX2P2, AC091078.1, AC112693.1, AC112693.2, AC091078.2, SEPHS1P2, AC110023.1.
- chr16:4,461,691–4,495,763, 1 gene, copy number 8 (within-gene range 2–8): NMRAL1.
- chr16:11,359,845–11,527,245, 1 gene, copy number 7 (within-gene range 2–7): AC099489.1.
- chr16:11,465,260–14,266,773, 54 genes, copy number 7: AC099489.3, LITAF, SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4, RSL1D1, AC007216.4, GSPT1, AC007216.3, COX6CP1, AC007216.2, AC007216.5, NPIPB2, TNFRSF17, UBL5P4, SNX29, AC007216.1, RPS23P6, AC007601.1, AC007601.2, AC092365.1, AC007598.2, AC007598.1, AC007598.3, AC131391.1, AC010333.1, AC010333.2, AC010333.3, CPPED1, MIR4718, AC109597.1, AC109597.2, AC092324.1, RPL35AP34, SHISA9, AC009134.1, U91319.1, AC003009.1, TMF1P1, U95743.1, ERCC4, RPS26P52, AC010401.1, AC010401.2, LINC02185, LINC02186, MRTFB, AC130650.2, AC130650.1, TVP23CP2.
- chr16:33,687,025–34,163,110, 30 genes, copy number 8: BMS1P8, ENPP7P13, AC136428.2, IGHV3OR16-12, AC136428.3, IGHV3OR16-13, AC136428.1, AC140658.6, AC140658.7, AC140658.2, IGHV3OR16-11, AC140658.3, ARHGAP23P1, IGHV3OR16-7, AC140658.4, IGHV3OR16-16, AC140658.1, AC140658.5, AC133561.1, BCAP31P1, AC133561.2, AC133561.4, AC133561.3, AC136932.1, DUX4L45, PCMTD1P2, DUX4L46, DUX4L47, LINC00273, RNA5-8SP2.
- chr16:35,734,393–49,066,729, 91 genes, copy number 7 (broad region; genes not listed).
- chr19:28,294,093–30,228,715, 43 genes, copy number 6–7 (within-gene range 2–7): AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1.
- chr20:33,980,679–64,327,972, 753 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,647. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
